Gene-level copy-number profile of tumor specimen TCGA-98-8020-01A from TCGA case TCGA-98-8020, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.2 years (20,509 days).
Specimen TCGA-98-8020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.135f38fa-9265-41a5-b6af-41c481698456.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-8020-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34ccd141-88b9-40d1-87aa-5c70fdf1daea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 39; copy number 2: 17,156; copy number 3: 21,507; copy number 4: 13,398; copy number 5: 4,391; copy number 6: 2,084; copy number 7: 446; copy number 8: 497; copy number 9: 43; copy number 10: 104; copy number 12: 32; copy number 15: 34; copy number 19: 58; copy number 32: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-8020-01A-11D-2243-01): tumor purity 0.46, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,242 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,647,988–59,533,898, 37 genes, copy number 8: HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA.
- chr4:106,921,802–111,331,518, 66 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr4:136,355,110–137,301,187, 5 genes, copy number 9: TERF1P3, AC093875.1, LINC02511, LINC02510, SERF1AP1.
- chr7:54,185,071–55,878,164, 43 genes, copy number 8–32: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2.
- chr8:46,028,804–47,068,323, 20 genes, copy number 7: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32.
- chr8:77,399,072–139,508,971, 855 genes, copy number 7–12 (broad region; genes not listed).
- chr11:37,938,601–39,261,213, 9 genes, copy number 7: LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P.
- chr11:66,975,277–70,436,584, 135 genes, copy number 10–19 (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 19: AP001271.1.
- chr13:88,494,789–89,280,240, 9 genes, copy number 8: LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13.
- chr18:22,413,599–22,419,294, 2 genes, copy number 7: CTAGE1, ATP7BP1.
- chr19:10,718,079–10,833,488, 1 gene, copy number 19 (within-gene range 6–19): DNM2.
- chr19:10,780,254–11,809,622, 59 genes, copy number 10–19: MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1, LDLR, MIR6886, SPC24, KANK2, DOCK6, AC011472.1, AC011472.5, AC011472.4, ANGPTL8, TSPAN16, AC011472.2, RAB3D, AC011472.3, TMEM205, CCDC159, PLPPR2, AC024575.1, SWSAP1, EPOR, RGL3, Y_RNA, CCDC151, PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1, ELOF1, ZNF627, ACP5, GAPDHP76, AC008543.1, ZNF887P, HNRNPA1P10, ZNF833P, ZNF823, AC008543.3, AC008543.2, ZNF441, AC008543.5, ZNF491.

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
